Somatic mutation profile of tumor specimen ALCH-B28H-TTP1-A (aliquot ALCH-B28H-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B28H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.8 years (24,383 days).
Specimen ALCH-B28H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b793ca8-e6cb-4354-ba39-b149dcdbd429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28H-NB1-A (Blood Derived Normal), aliquot ALCH-B28H-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a2cb844-dfb0-4ad6-9121-da19a55ad3e4

The open-access MAF lists 305 somatic variants for this specimen: 225 protein-altering or splice-affecting, 42 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 42, Nonsense Mutation 21, Intron 18, Frame Shift Del 9, RNA 8, 5'UTR 6, Splice Site 4, 5'Flank 3, Splice Region 2, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAGS | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as rs762205848; ClinVar: likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67960494; called by muse, mutect2, varscan2
- OTC | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72556260, CM930525, COSV99234415; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRKCG | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918511, CM031334; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.10316G>T p.G3439V | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs760608174; called by muse, mutect2, varscan2
- AGA | c.961T>A p.S321T | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV99219395; called by muse, varscan2
- AGBL5 | c.2510C>A p.P837Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs756390314; called by muse, mutect2, varscan2
- AK5 | c.983G>A p.G328D (on ENST00000354567 / NM_174858.3; = p.G302D on NM_012093.4) | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767465345; called by muse, mutect2, varscan2
- ANKRD30B | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57703857; called by muse, mutect2, varscan2
- ANKUB1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762463717; called by muse, mutect2, varscan2
- APOB | c.5956C>T p.Q1986* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV51951185; called by muse, mutect2, varscan2
- ARMC12 | c.196G>T p.D66Y (on ENST00000373866 / NM_001286574.2; = p.D93Y on NM_145028.5) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55359951, COSV99849347; called by muse, mutect2, varscan2
- ATP10B | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV58780901; called by muse, mutect2, varscan2
- ATP13A2 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58701156, COSV58704128; called by muse, mutect2, varscan2
- BCHE | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1301323421; called by muse, mutect2, varscan2
- C1orf105 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV62959363; called by muse, mutect2, varscan2
- C1orf167 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.18); catalogued as rs753637610, COSV57174013; called by mutect2, varscan2
- CAMSAP3 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1306228130; called by muse, varscan2
- CCT8L2 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as COSV100743003, COSV63461651; called by muse, mutect2, varscan2
- CDC73 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.096); catalogued as rs1060500016, COSV66471058; ClinVar: uncertain significance; called by muse, mutect2
- CDH12 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66430216; called by muse, mutect2
- CDH18 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as rs762170759, COSV56956664; called by muse, mutect2, varscan2
- CEP164 | c.3913G>T p.D1305Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54039054, COSV54042392; called by muse, mutect2, varscan2
- COL22A1 | c.3956C>T p.P1319L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1247165542, COSV57341381; called by muse, mutect2, varscan2
- COL22A1 | c.2518G>C p.G840R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277192, COSV57345150; called by muse, mutect2, varscan2
- COL6A6 | c.4336G>T p.G1446C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649670; called by muse, mutect2, varscan2
- COL9A1 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV61829552; called by muse, mutect2, varscan2
- CPXCR1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52163369; called by muse, mutect2, varscan2
- CSMD1 | c.10258G>T p.G3420C (on ENST00000520002; = p.G3419C on NM_033225.6) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100152443; called by muse, mutect2, varscan2
- CSMD1 | c.6151C>T p.P2051S (on ENST00000520002; = p.P2050S on NM_033225.6) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753451258; called by muse, mutect2, varscan2
- CSMD3 | c.2513G>A p.G838E (on ENST00000297405 / NM_001363185.1; = p.G734E on NM_052900.3) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52250069; called by muse, varscan2
- CYSLTR1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs758713318; called by muse, mutect2, varscan2
- DCC | c.2504C>A p.T835N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59102931; called by muse, mutect2, varscan2
- DDX18 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99604838; called by muse, mutect2
- DNAH3 | c.8615C>G p.A2872G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs779528371; called by muse, mutect2, varscan2
- DOC2B | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as rs1487509582; called by muse, mutect2, varscan2
- DYNC2I1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs376591105; called by muse, mutect2, varscan2
- FAM135B | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs370460671, COSV52731262; called by muse, mutect2, varscan2
- FAM83G | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV58757414; called by muse, mutect2, varscan2
- FCRL4 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV54859282; called by muse, mutect2
- FLYWCH1 | c.978G>C p.M326I (on ENST00000253928 / NM_001308068.2; = p.M325I on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54149096; called by muse, mutect2, varscan2
- GABRA4 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.989); catalogued as COSV51937253; called by muse, mutect2
- GOLGA8R | c.871+1G>A p.X291_splice | Splice Site (SNP) | VAF 16/250 reads (6%) | catalogued as rs760212740; called by muse, mutect2
- GPR158 | c.3470C>A p.S1157* | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | catalogued as COSV100893130; called by muse, mutect2, varscan2
- GTF3C4 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs769535681; called by muse, mutect2, varscan2
- HECTD4 | c.7028C>T p.A2343V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66398473; called by muse, mutect2, varscan2
- HERC1 | c.12703G>A p.V4235I | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs755829541; called by muse, mutect2, varscan2
- HFM1 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1431103308; called by muse, mutect2, varscan2
- KRT3 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs200393349; called by mutect2, varscan2
- MAP3K6 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.152); catalogued as COSV99052202; called by muse, varscan2
- MDH2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782459104, COSV59884044, COSV59885655; called by muse, mutect2
- NAV3 | c.1320del p.V442Cfs*50 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | catalogued as COSV57064769; called by mutect2, pindel, varscan2
- NDST4 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99998216; called by muse, mutect2, varscan2
- NLRP12 | c.1122C>A p.F374L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs766035651; called by muse, mutect2, varscan2
- NLRP12 | c.863del p.R288Pfs*40 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV60743363; called by mutect2, pindel, varscan2
- OBI1 | c.1010A>T p.N337I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs774614872; called by muse, mutect2, varscan2
- OR4K1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53461119, COSV53462369; called by muse, mutect2, varscan2
- OR5K2 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71143203; called by muse, mutect2, varscan2
- OR6F1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100128933; called by muse, mutect2, varscan2
- OR9Q2 | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV61111553; called by muse, mutect2, varscan2
- PHF14 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs1384407575; called by muse, mutect2, varscan2
- PKHD1 | c.6020G>T p.G2007V | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as CM149118; called by muse, mutect2, varscan2
- PLCD3 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1160131157; called by muse, mutect2, varscan2
- PLG | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804527; called by muse, mutect2, varscan2
- PRDM13 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV65029556; called by muse, mutect2, varscan2
- PTPRZ1 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as COSV66447894; called by muse, mutect2, varscan2
- RASA3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1200479395; called by muse, mutect2, varscan2
- RASGRP3 | c.1240C>T p.P414S (on ENST00000402538 / NM_001349975.2; = p.P413S on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.434); catalogued as COSV101274917; called by muse, varscan2
- RIMBP2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752540968; called by muse, mutect2, varscan2
- RUNDC3B | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs866004904; called by muse, mutect2, varscan2
- SALL4 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as rs772877973; called by muse, mutect2, varscan2
- SCN4A | c.3394C>G p.R1132G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV101438280; called by mutect2, varscan2
- SEC23B | c.1180A>G p.K394E | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1244547269; called by muse, mutect2, varscan2
- SOX10 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61005041; called by muse, mutect2, varscan2
- STXBP5L | c.2093A>G p.N698S | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs774030165; called by muse, mutect2, varscan2
- SYNE1 | c.7009G>A p.E2337K (on ENST00000367255 / NM_182961.4; = p.E2344K on NM_033071.3) | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1385505345; called by muse, mutect2
- TCP11L2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763401853, COSV54429024; called by mutect2, varscan2
- TRIM2 | c.1582C>G p.R528G (on ENST00000437508; = p.R555G on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58635738; called by muse, mutect2, varscan2
- TRIM2 | c.1583G>C p.R528P (on ENST00000437508; = p.R555P on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58632353; called by muse, mutect2, varscan2
- TSPAN2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 37/200 reads (19%) | catalogued as COSV65690485; called by muse, mutect2, varscan2
- TTN | c.48197C>A p.T16066N (on ENST00000591111; = p.T8642N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/245 reads (5%) | PolyPhen benign (0.295); catalogued as COSV59988403; called by muse, mutect2
- USP34 | c.3989G>T p.C1330F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as rs1279734522, COSV68401873; called by muse, mutect2, varscan2
- VWA3B | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 38/196 reads (19%) | catalogued as rs1486260168; called by muse, mutect2, varscan2
- ZIC1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.902); catalogued as rs772678194, COSV99292295; called by muse, varscan2
- ZNF280A | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV57480163, COSV57481635; called by muse, mutect2, varscan2
- ZNF550 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1055648752; called by muse, mutect2, varscan2
- ZNF679 | c.1211del p.G404Efs*19 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV55378362; called by mutect2, pindel
- ZNF880 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs879077292; called by muse, mutect2, varscan2
- ABCB4 | c.3057del p.Y1020Tfs*6 | Frame Shift Del (DEL) | VAF 37/317 reads (12%) | called by mutect2, pindel, varscan2
- ACCS | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ADAM2 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGB | c.4930G>T p.A1644S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ADGRG4 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ADPRHL1 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- ADRA2A | c.350del p.G117Afs*42 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- AGBL5 | c.2509C>G p.P837A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ANK3 | c.3106A>G p.M1036V (on ENST00000280772 / NM_001320874.2; = p.M170V on NM_001149.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- APOBEC3G | c.524G>T p.W175L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ARL5A | c.492-1G>T p.X164_splice | Splice Site (SNP) | VAF 48/305 reads (16%) | called by muse, mutect2, varscan2
- ARRDC5 | c.274A>C p.T92P (on ENST00000381781; = p.T78P on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ASIC5 | c.930C>A p.Y310* | Nonsense Mutation (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- ATP10D | c.940T>A p.L314I | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ATP13A3 | c.3101A>T p.Y1034F | Missense Mutation (SNP) | VAF 62/504 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, varscan2
- BRINP3 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BRWD3 | c.3830A>T p.D1277V | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BRWD3 | c.2195G>T p.R732I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C5orf51 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 70/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C9orf43 | c.325T>G p.C109G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- CADPS2 | c.926T>A p.L309* | Nonsense Mutation (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- CAPS2 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CBY2 | c.571A>T p.K191* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- CCN3 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILK1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNN3 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRACR2A | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CSMD3 | c.633T>A p.D211E | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTNNA3 | c.1724C>A p.T575K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.82); called by muse, mutect2
- CUBN | c.9924G>T p.W3308C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF8L1 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DCC | c.3479T>C p.M1160T | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DCHS2 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX60 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DGKK | c.1542A>T p.Q514H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLEC1 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNALI1 | c.811C>T p.Q271* (on ENST00000296218; = p.Q249* on NM_003462.5) | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- DOCK10 | c.244-2A>G p.X82_splice | Splice Site (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- ECE1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EIF2S3 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- EPHA6 | c.1388G>C p.C463S | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- F11 | c.1828A>G p.N610D | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- FAM135A | c.4291C>T p.H1431Y (on ENST00000370479 / NM_001351599.1; = p.H1218Y on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL1 | c.494C>G p.T165R | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FOXRED1 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- FPR3 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- FREM2 | c.7290G>C p.L2430F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GABRP | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2
- GDF10 | c.1335del p.D446Ifs*3 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- GIPC3 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- GNAT3 | c.590+1G>A p.X197_splice | Splice Site (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- GRIK1 | c.1606T>A p.Y536N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- H4C2 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- HAS1 | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.14042A>G p.Y4681C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- HNRNPDL | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPRID1 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IZUMO3 | c.104T>G p.L35W | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- KCMF1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- KEAP1 | c.840C>G p.F280L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- KRTAP15-1 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.483T>G p.D161E | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGEB18 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEC1 | c.2556G>C p.Q852H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MED12L | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MGAT2 | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- MIDN | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- MMP26 | c.338A>T p.H113L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- MRFAP1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2, varscan2
- MRPL39 | c.861A>T p.Q287H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC12 | c.713T>A p.L238H (on ENST00000379442; = p.L95H on NM_001164462.1) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MYO1D | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MYO7A | c.1908C>G p.I636M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYO7B | c.4993G>A p.D1665N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- N4BP2 | c.2114T>G p.M705R | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- N4BP2L2 | c.2192G>A p.R731K (on ENST00000674422; = p.R302K on NM_033111.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NAA25 | c.2872dup p.E958Gfs*8 | Frame Shift Ins (INS) | VAF 28/286 reads (10%) | called by mutect2, pindel
- NEUROD4 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NLRP5 | c.2344C>A p.H782N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOBOX | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- NRG3 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR2J3 | c.540T>G p.F180L | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8J3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH15 | c.3973G>T p.E1325* | Nonsense Mutation (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PCSK9 | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- PDS5A | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PIGK | c.150G>T p.V50= | Splice Region (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- PNMA8A | c.1222del p.Q408Sfs*40 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- PRDM5 | c.1697C>A p.T566K | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, varscan2
- PSMA8 | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPDC1 | c.1258G>T p.V420F (on ENST00000375360 / NM_177995.3; = p.V472F on NM_152422.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- PTPRD | c.5275C>A p.P1759T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRZ1 | c.896C>G p.S299* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- PXDN | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2
- RALGAPA2 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ROBO2 | c.1927A>T p.N643Y | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ROBO2 | c.2213C>A p.A738D | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RTKN | c.1314A>T p.K438N (on ENST00000272430 / NM_001015055.2; = p.K425N on NM_033046.2) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RYR1 | c.3160C>A p.P1054T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SCN7A | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SEMA5A | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SESTD1 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SHOX | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLC22A11 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC9A6 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMC4 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SPEF2 | c.2794C>T p.H932Y | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- SPHKAP | c.3152A>T p.E1051V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SPRED3 | c.200A>T p.K67M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- SRRM4 | c.507C>G p.H169Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SSU72P8 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- STAB2 | c.4577A>T p.K1526M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2761A>G p.I921V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX50 | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TRAPPC10 | c.3092T>G p.F1031C | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM64B | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- TRPM5 | c.3128T>A p.L1043Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBB8B | c.1169G>T p.R390M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, varscan2
- TXNL4B | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UBC | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ULK1 | c.615G>A p.W205* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- UROC1 | c.358del p.Q120Rfs*4 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- USH2A | c.11063C>A p.P3688H | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- VAV3 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VGLL3 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- VSIG10L | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- WDR17 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XIRP2 | c.5522T>C p.V1841A (on ENST00000628543; = p.V2016A on NM_152381.6) | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF23 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF292 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ZNF534 | c.973A>T p.S325C (on ENST00000332323 / NM_001143939.3; = p.S312C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF749 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- ZRANB2 | c.986del p.K329Rfs*10 | Frame Shift Del (DEL) | VAF 35/203 reads (17%) | called by mutect2, pindel, varscan2
- ZWINT | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); called by muse, mutect2
- ABCG8 | c.885G>T p.G295= | Silent (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- ATG2B | c.4551A>G p.A1517= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.762G>T p.L254= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs765480746, COSV53418710; called by muse, mutect2, varscan2
- B3GNT6 | c.774C>A p.R258= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV62829069; called by muse, mutect2, varscan2
- BST1 | c.819C>T p.D273= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1116C>A p.S372= | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- CR1 | c.5694C>T p.S1898= | Silent (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- CRACR2A | c.1233G>A p.V411= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- CSRNP3 | c.894C>T p.H298= | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as rs1362943031, COSV100085074; called by muse, mutect2
- DTX3L | c.1113C>G p.A371= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV99950085; called by muse, mutect2, varscan2
- ERI2 | c.330G>A p.L110= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- FSCB | c.1260C>A p.T420= | Silent (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- GUCY1A2 | c.468G>A p.Q156= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV99972079, COSV99972106; called by muse, mutect2, varscan2
- LRBA | c.1704G>A p.L568= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs763651221; called by muse, mutect2, varscan2
- MANBA | c.1356A>G p.E452= (on ENST00000642252; = p.E406= on NM_005908.4) | Silent (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- MMUT | c.12T>G p.A4= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV51275050; called by muse, mutect2, varscan2
- MROH2B | c.4443A>C p.P1481= | Silent (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- MYOF | c.3270C>T p.A1090= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- NRXN1 | c.1590C>A p.A530= | Silent (SNP) | VAF 48/264 reads (18%) | called by muse, mutect2, varscan2
- OR11L1 | c.255G>T p.L85= | Silent (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- OR2F2 | c.534C>A p.S178= | Silent (SNP) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- OR2G6 | c.135C>A p.L45= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as COSV58573593; called by muse, mutect2, varscan2
- OR2M3 | c.495C>T p.S165= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV71759314; called by muse, mutect2
- PARD3B | c.1803G>A p.E601= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2
- PAXIP1 | c.2496C>T p.P832= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as COSV101249392; called by muse, mutect2, varscan2
- PCDHA2 | c.147G>T p.A49= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs144324178, COSV65370513; called by muse, mutect2, varscan2
- PCDHB5 | c.291G>T p.G97= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV50651402; called by muse, mutect2, varscan2
- PCLO | c.14901A>G p.A4967= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV61658098; called by muse, mutect2, varscan2
- PDZD2 | c.2838C>A p.P946= | Silent (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- PREPL | c.1623G>T p.T541= | Silent (SNP) | VAF 40/293 reads (14%) | catalogued as COSV53218347; called by muse, mutect2, varscan2
- PXDNL | c.333T>C p.H111= | Silent (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.6960G>A p.V2320= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs1306680684, COSV100769484, COSV63703499; called by muse, mutect2, varscan2
- SFMBT1 | c.1092G>A p.Q364= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- SYT12 | c.96G>T p.L32= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- TERT | c.2214G>A p.T738= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs200858212; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM273 | c.12G>T p.G4= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100939806; called by muse, mutect2
- TMEM63C | c.2046C>T p.L682= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV53607280; called by muse, mutect2, varscan2
- ZFP82 | c.6C>G p.A2= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- ZNF470 | c.456G>A p.Q152= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- ZNF536 | c.1794C>T p.L598= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1255298532; called by muse, mutect2, varscan2
- ZNF727 | c.1077G>A p.K359= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- ZNF831 | c.2220C>A p.P740= | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, varscan2
- AC103993.1 | n.117G>C | RNA (SNP) | VAF 31/172 reads (18%) | catalogued as rs1221912945; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827225 T>G | 3'Flank (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- ATIC | c.1504-372G>T | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- C2orf83 | n.371del | RNA (DEL) | VAF 36/131 reads (27%) | called by mutect2, pindel, varscan2
- CARD16 | c.7+18C>G | Intron (SNP) | VAF 31/174 reads (18%) | called by muse, mutect2, varscan2
- CCKBR | c.811+18G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs200603102; called by muse, mutect2, varscan2
- CCNYL2 | n.624-2639G>T | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- CCNYL2 | n.624-2640G>C | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- CHEK2 | c.721+116G>A | Intron (SNP) | VAF 24/64 reads (38%) | catalogued as rs1196006038; called by muse, mutect2, varscan2
- CNGB1 | c.*31C>A | 3'UTR (SNP) | VAF 14/41 reads (34%) | catalogued as rs750832506; called by muse, mutect2, varscan2
- CTBP2 | c.59-2122G>T | Intron (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- CTDP1 | chr18:79679474 G>C | 5'Flank (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.3235C>T | RNA (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- DHX37 | c.3388+87G>T | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- EGFEM1P | n.515C>T | RNA (SNP) | VAF 16/67 reads (24%) | catalogued as rs1338196946; called by muse, mutect2
- EPHB1 | c.805+25963G>T | Intron (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- FHL1 | chrX:136146913 C>A | 5'Flank (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+251102G>T | Intron (SNP) | VAF 29/161 reads (18%) | catalogued as COSV66178073; called by muse, mutect2, varscan2
- KRT6A | c.-38C>A | 5'UTR (SNP) | VAF 22/108 reads (20%) | catalogued as rs1280105759; called by muse, varscan2
- MAFK | c.-25C>T | 5'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+883G>T | Intron (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100165758; called by muse, mutect2
- MASP2 | c.-23C>T | 5'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- MED24 | c.2624-41G>T | Intron (SNP) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- MTUS2 | c.3118-11152C>A | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604538 T>C | 5'Flank (SNP) | VAF 18/72 reads (25%) | catalogued as rs750297532; called by muse, mutect2, varscan2
- P4HTM | c.724+88del | Intron (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- RNF216 | c.874-166G>C | Intron (SNP) | VAF 24/122 reads (20%) | called by mutect2, varscan2
- SATL1 | c.-446C>T | 5'UTR (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- SSNA1 | c.-6T>A | 5'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as rs1366918887; called by muse, mutect2, varscan2
- SUMO2P21 | n.258G>T | RNA (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5668A>G | Intron (SNP) | VAF 25/263 reads (10%) | catalogued as COSV59549841; called by muse, mutect2, varscan2
- TBC1D3P2 | n.827C>A | RNA (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- TGM6 | c.-8G>A | 5'UTR (SNP) | VAF 25/123 reads (20%) | catalogued as rs1297574808; called by muse, mutect2, varscan2
- TTN | c.34265-5670C>T | Intron (SNP) | VAF 19/111 reads (17%) | catalogued as COSV100596006; called by muse, mutect2, varscan2
- TTN | c.10361-4252C>A | Intron (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- TUBB7P | n.1061G>T | RNA (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- XIST | n.11400C>A | RNA (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.*113C>T | 3'UTR (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
